Somatic mutation profile of tumor specimen TCGA-28-1747-01C (aliquot TCGA-28-1747-01C-01W-0837-08) from TCGA case TCGA-28-1747, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 44.6 years (16,301 days).
Specimen TCGA-28-1747-01C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52a02fe9-b4dd-4989-ae83-4423760d8bfe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-28-1747-10B (Blood Derived Normal), aliquot TCGA-28-1747-10B-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6f68649-ee2d-4400-9b02-ae02f705c73a

The open-access MAF lists 49 somatic variants for this specimen: 40 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 31, Silent 9, Frame Shift Del 4, Frame Shift Ins 3, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BMPR2 | c.1157A>G p.E386G | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1085307307, CM043450, CM081186, CM134744, COSV65813197; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EGFR | c.322A>G p.R108G | Missense Mutation (SNP) | VAF 128/2102 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519888, COSV51812540; ClinVar: likely pathogenic; called by muse, mutect2
- EGFR | c.910C>T p.H304Y | Missense Mutation (SNP) | VAF 297/1828 reads (16%) | hotspot (GDC flag); SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV51765787; called by muse, mutect2, varscan2
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 196/1527 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.2491G>A p.E831K | Missense Mutation (SNP) | VAF 83/238 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as rs1330177914, COSV60623615; called by muse, mutect2, varscan2
- ADAM29 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 170/517 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs753780341, COSV63667689; called by muse, mutect2, varscan2
- AK7 | c.1982G>A p.R661Q | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.06); catalogued as rs983382324, COSV50870153; called by muse, mutect2, varscan2
- ANGPT4 | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 132/338 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs949137202, COSV67922715; called by muse, mutect2, varscan2
- CENATAC | c.836dup p.D280Rfs*8 | Frame Shift Ins (INS) | VAF 6/56 reads (11%) | catalogued as rs1214317268; called by pindel, varscan2
- CGB5 | c.82C>T p.R28W | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs1425976710; called by mutect2, varscan2
- CLCA1 | c.1298A>G p.H433R | Missense Mutation (SNP) | VAF 54/171 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV52330809; called by muse, mutect2, varscan2
- DCLRE1B | c.1142G>A p.W381* | Nonsense Mutation (SNP) | VAF 79/211 reads (37%) | catalogued as COSV65813585; called by muse, mutect2, varscan2
- FAM50B | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.153); catalogued as rs766522202, COSV66655238; called by muse, mutect2, varscan2
- GPX5 | c.187C>T p.H63Y | Missense Mutation (SNP) | VAF 175/456 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV69079817; called by muse, mutect2, varscan2
- GRAMD1A | c.320T>C p.I107T | Missense Mutation (SNP) | VAF 88/216 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58768847; called by muse, mutect2, varscan2
- HEXIM1 | c.101del p.P34Qfs*52 | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | catalogued as rs767170073; called by mutect2, pindel, varscan2
- HS3ST3A1 | c.647C>T p.T216M | Missense Mutation (SNP) | VAF 117/329 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs948840702, COSV52378932; called by muse, mutect2, varscan2
- IL18R1 | c.351_352del p.H117Qfs*5 | Frame Shift Del (DEL) | VAF 13/39 reads (33%) | catalogued as rs750865901; called by pindel, varscan2
- LIPG | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 69/218 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs758552549, COSV54298012; called by muse, mutect2, varscan2
- MOCS3 | c.1045G>C p.A349P | Missense Mutation (SNP) | VAF 157/520 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.075); catalogued as COSV54867707; called by muse, mutect2, varscan2
- MUC16 | c.13958C>A p.T4653K | Missense Mutation (SNP) | VAF 150/473 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.556); catalogued as COSV67488624; called by muse, mutect2, varscan2
- NYAP2 | c.945dup p.K316Qfs*116 | Frame Shift Ins (INS) | VAF 16/108 reads (15%) | catalogued as rs758750309; called by mutect2, varscan2
- OR2A7 | c.52G>A p.V18I | Missense Mutation (SNP) | VAF 131/1494 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs531461622, COSV71827384; called by muse, mutect2
- OR5K4 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 638/1598 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61584081; called by muse, mutect2, varscan2
- PCLO | c.5234C>T p.P1745L | Missense Mutation (SNP) | VAF 406/1501 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764070940, COSV61659877; called by muse, mutect2, varscan2
- PCSK1 | c.1213C>T p.R405* | Nonsense Mutation (SNP) | VAF 68/275 reads (25%) | catalogued as rs1252953022, CM136267, COSV60737332; called by muse, mutect2, varscan2
- PLA2G4A | c.2033T>G p.F678C | Missense Mutation (SNP) | VAF 89/233 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV66556595; called by muse, mutect2, varscan2
- PPM1H | c.640G>A p.G214R | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.657); catalogued as COSV57378757; called by muse, mutect2, varscan2
- PTPRH | c.3208G>A p.V1070I | Missense Mutation (SNP) | VAF 63/202 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.45); catalogued as rs140496718; called by muse, mutect2, varscan2
- RYR3 | c.4219G>A p.V1407M | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.172); catalogued as rs1430659504, COSV66797525, COSV66806794; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCG2 | c.242A>G p.Y81C | Missense Mutation (SNP) | VAF 137/375 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as rs1213485165, COSV59541673; called by muse, mutect2, varscan2
- TRPM2 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1212502618, COSV55969588; called by muse, mutect2, varscan2
- TSPAN7 | c.516dup p.S173Qfs*8 | Frame Shift Ins (INS) | VAF 10/86 reads (12%) | catalogued as rs752121179; called by mutect2, varscan2
- TUBB4A | c.925C>T p.R309C | Missense Mutation (SNP) | VAF 101/302 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.186); catalogued as rs1386587020, COSV51152536; called by muse, mutect2, varscan2
- ZFYVE16 | c.4144G>A p.V1382M | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs550518358, COSV62017424; called by muse, mutect2, varscan2
- ZSCAN29 | c.1066G>A p.D356N | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs781407532, COSV53021144; called by muse, mutect2, varscan2
- ALX4 | c.574del p.D192Tfs*58 | Frame Shift Del (DEL) | VAF 66/231 reads (29%) | called by mutect2, pindel, varscan2
- GREM1 | c.217G>T p.V73L | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- TRAV13-1 | c.231del p.D78Tfs*8 | Frame Shift Del (DEL) | VAF 254/940 reads (27%) | called by mutect2, pindel, varscan2
- XPO6 | c.3010G>C p.E1004Q | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2
- ACOT12 | c.621G>A p.A207= | Silent (SNP) | VAF 414/1085 reads (38%) | catalogued as rs150238683, COSV56897783; called by muse, mutect2, varscan2
- CCDC146 | c.228C>T p.D76= | Silent (SNP) | VAF 26/609 reads (4%) | catalogued as rs1449031957; called by muse, mutect2
- GRIN2A | c.390C>T p.G130= | Silent (SNP) | VAF 39/105 reads (37%) | catalogued as COSV58055118; called by muse, mutect2, varscan2
- NT5C1B | c.546G>A p.S182= (on ENST00000359846 / NM_001199086.2; = p.S122= on NM_033253.4) | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs1363084909, COSV58394346; called by muse, mutect2, varscan2
- PCDHA9 | c.2004G>A p.S668= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as COSV65324280; called by muse, mutect2, varscan2
- SLC28A2 | c.363G>A p.S121= | Silent (SNP) | VAF 57/164 reads (35%) | catalogued as rs771965795, COSV61665129; called by muse, mutect2, varscan2
- TG | c.4263C>T p.T1421= | Silent (SNP) | VAF 113/359 reads (31%) | catalogued as COSV55092406; called by muse, mutect2, varscan2
- ZNF169 | c.357C>A p.I119= | Silent (SNP) | VAF 21/260 reads (8%) | called by muse, mutect2
- ZNF610 | c.324G>A p.R108= | Silent (SNP) | VAF 122/340 reads (36%) | catalogued as COSV58346385; called by muse, mutect2, varscan2
